Somatic mutation profile of tumor specimen 0DOA3R from CCDI case PBCCFU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Teratoma, malignant, NOS; Tissue or organ of origin: Pineal gland; Age at diagnosis: 11.7 years (4,275 days).
Specimen 0DOA3R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6624e311-a138-4350-8c82-35d08e971986.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOA27 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16cfb761-2db9-4015-b490-7e9344aa35eb

The open-access MAF lists 9 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, 3'UTR 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- USHBP1 | c.1072G>T p.V358F | Missense Mutation (SNP) | VAF 52/332 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as rs1057207611, COSV53102427; called by muse, mutect2, varscan2
- KPNA5 | c.329T>A p.L110Q | Missense Mutation (SNP) | VAF 23/858 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2
- MYOM1 | c.2713G>A p.E905K | Missense Mutation (SNP) | VAF 82/534 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- PPAT | c.766G>A p.V256M | Missense Mutation (SNP) | VAF 89/673 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- ADGRA3 | c.3747T>C p.S1249= | Silent (SNP) | VAF 111/635 reads (17%) | catalogued as rs202141366; called by muse, mutect2, varscan2
- MYADML2 | c.735C>T p.A245= | Silent (SNP) | VAF 34/581 reads (6%) | catalogued as rs1397377231; called by muse, mutect2
- AC005833.1 | c.*83A>T | 3'UTR (SNP) | VAF 8/178 reads (4%) | called by muse, mutect2
- GOLGA6A | c.1426-60C>T | Intron (SNP) | VAF 11/103 reads (11%) | catalogued as rs1432821351; called by muse, varscan2
- SLC35G3 | c.-76A>G | 5'UTR (SNP) | VAF 20/226 reads (9%) | catalogued as rs1567776580; called by muse, mutect2
